Somatic mutation profile of tumor specimen TCGA-A6-2674-01B (aliquot TCGA-A6-2674-01B-04D-A270-10) from TCGA case TCGA-A6-2674, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 72.0 years (26,292 days).
Specimen TCGA-A6-2674-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fcc1e471-d5e6-4e96-b925-895cb4361acf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-2674-10A (Blood Derived Normal), aliquot TCGA-A6-2674-10A-01D-A270-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f573d587-b76c-458d-8313-ca4c5e786d75

The open-access MAF lists 85 somatic variants for this specimen: 56 protein-altering or splice-affecting, 26 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 26, Nonsense Mutation 4, Splice Site 1, Splice Region 1, 5'Flank 1, Intron 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 22/117 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SIN3A | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as rs1555444885, COSV100845253; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACMSD | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs147728377; called by muse, mutect2, varscan2
- ADCY2 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs369487048, COSV57871248; called by muse, mutect2, varscan2
- ANKRD11 | c.2213G>A p.R738H | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs370690185; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF3 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99576076; called by muse, mutect2, varscan2
- CCM2L | c.1316G>A p.R439Q (on ENST00000452892 / NM_001365692.1; = p.G418R on NM_080625.4) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as rs749780270, COSV52953198; called by muse, mutect2, varscan2
- CHRM2 | c.1363C>G p.L455V | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1470994649, COSV100282099, COSV57767109; called by muse, varscan2
- CLIP1 | c.4246C>T p.R1416C (on ENST00000620786 / NM_001247997.1; = p.R1405C on NM_002956.2) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs999756920, COSV100211294; called by muse, mutect2, varscan2
- CPNE6 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99393870; called by muse, mutect2, varscan2
- CRACD | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); catalogued as COSV99950127; called by mutect2, varscan2
- CTNS | c.254C>G p.S85C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.415); catalogued as rs756405315, COSV99251644; called by muse, mutect2, varscan2
- DAXX | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.223); catalogued as COSV56466160; called by muse, mutect2
- DOT1L | c.133T>G p.C45G | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101288882; called by muse, mutect2, varscan2
- DPP6 | c.1195C>G p.L399V (on ENST00000377770 / NM_001364500.2; = p.L337V on NM_001936.5) | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.947); catalogued as COSV100128619; called by muse, varscan2
- GPR137B | c.969C>T p.T323= | Splice Region (SNP) | VAF 12/88 reads (14%) | catalogued as COSV100858583; called by muse, mutect2, varscan2
- HBG2 | c.386C>A p.A129D | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100400720; called by muse, mutect2, varscan2
- HMCN1 | c.16783C>T p.R5595* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs1412752744, COSV54884056, COSV99633533; called by muse, mutect2, varscan2
- IFNA17 | c.241C>A p.H81N | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV101303486, COSV69738160; called by muse, mutect2, varscan2
- KRT34 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as rs776876023, COSV67449815; called by muse, mutect2, varscan2
- MRPL20 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs775815488, COSV61224529; called by muse, mutect2, varscan2
- NAV3 | c.7105A>C p.S2369R (on ENST00000397909 / NM_001024383.2; = p.S2347R on NM_014903.6) | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV57099611; called by muse, mutect2
- OR5H6 | c.30G>C p.Q10H | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.36); catalogued as COSV101051826; called by muse, mutect2
- OR6C74 | c.107G>T p.S36I | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as COSV59607519; called by muse, mutect2, varscan2
- OSBP | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99803483; called by muse, mutect2, varscan2
- PAH | c.376C>G p.Q126E | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100188493; called by muse, mutect2, varscan2
- PCDH15 | c.3834A>C p.Q1278H | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57406823; called by muse, mutect2
- PCDH9 | c.3469C>A p.P1157T (on ENST00000377865 / NM_203487.3; = p.P1123T on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV100124187; called by muse, mutect2, varscan2
- PCDHB2 | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.003); catalogued as rs782061095, COSV52029412, COSV99523661; called by muse, mutect2, varscan2
- PLCE1 | c.788A>G p.Y263C | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV99597644; called by muse, mutect2
- RFC1 | c.3075G>A p.M1025I (on ENST00000381897 / NM_001363496.2; = p.M1024I on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.299); catalogued as rs1334781039, COSV62901398; called by muse, mutect2, varscan2
- RHOT1 | c.1300G>A p.V434I | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs752714402, COSV100447639; called by muse, mutect2, varscan2
- RYR2 | c.10012G>T p.D3338Y | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV100773213; called by muse, mutect2, varscan2
- SOBP | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.571); catalogued as COSV58004112; called by muse, mutect2, varscan2
- SOX1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58378395; called by muse, mutect2, varscan2
- SPEF2 | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56796378, COSV99215005; called by muse, mutect2, varscan2
- SPP2 | c.133A>T p.S45C | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as COSV51446885; called by muse, mutect2, varscan2
- SYNE1 | c.7900C>A p.Q2634K (on ENST00000367255 / NM_182961.4; = p.Q2641K on NM_033071.3) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV99582823; called by mutect2, varscan2
- TEP1 | c.4954C>T p.H1652Y | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99403441; called by muse, mutect2, varscan2
- TFEB | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1311125282, COSV100026507; called by mutect2, varscan2
- TMEM151A | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as rs571174732, COSV99046246; called by muse, mutect2, varscan2
- TMEM255B | c.602T>C p.V201A | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.335); catalogued as COSV64705038; called by muse, mutect2, varscan2
- TMEM43 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.84); catalogued as rs570836197, COSV100044603; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMTC3 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 32/288 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs368224038; called by muse, mutect2, varscan2
- TRPC4 | c.2872G>T p.D958Y (on ENST00000379705 / NM_016179.4; = p.D963Y on NM_003306.3) | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as COSV59022019; called by muse, mutect2, varscan2
- TRRAP | c.2975A>G p.N992S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs781892964; called by muse, mutect2, varscan2
- TTN | c.75931G>A p.V25311I (on ENST00000591111; = p.V17887I on NM_003319.4) | Missense Mutation (SNP) | VAF 18/134 reads (13%) | PolyPhen benign (0); catalogued as rs371362606; ClinVar: likely benign / benign / uncertain significance; called by muse, mutect2, varscan2
- USPL1 | c.413A>G p.N138S | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as rs764273440, COSV99687640; called by muse, mutect2, varscan2
- ZNF562 | c.758T>G p.V253G (on ENST00000453372 / NM_001130032.2; = p.V181G on NM_017656.4) | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99530901; called by muse, mutect2, varscan2
- ANKRD30A | c.509A>C p.K170T (on ENST00000611781; = p.K114T on NM_052997.2) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, varscan2
- CCL3L3 | c.116C>A p.T39N | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- CEP104 | c.2566G>T p.E856* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | called by muse, varscan2
- ELF3 | c.799_805+6del p.X267_splice | Splice Site (DEL) | VAF 19/76 reads (25%) | called by mutect2, varscan2
- H4-16 | c.111_115dup p.A39Vfs*30 | Frame Shift Ins (INS) | VAF 4/41 reads (10%) | called by mutect2, varscan2
- OR52J3 | c.634C>A p.L212M | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PSD4 | c.2160C>G p.N720K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- AHDC1 | c.531C>T p.I177= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV55942063; called by muse, mutect2, varscan2
- CAD | c.3630G>A p.L1210= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV99255971; called by muse, varscan2
- CSMD2 | c.93C>T p.H31= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs373612518; called by muse, mutect2, varscan2
- DNMT1 | c.3774C>T p.Y1258= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1377297716; called by muse, varscan2
- ESPNL | c.1047G>A p.T349= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as rs371983774; called by muse, mutect2
- FAM155A | c.153G>T p.L51= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV65590902; called by muse, mutect2
- FLT4 | c.4062C>T p.R1354= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs762533367, COSV56104340, COSV56123048, COSV99989397; called by mutect2, varscan2
- GDF7 | c.1263C>T p.S421= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs747585645, COSV99694248; called by muse, varscan2
- GPATCH1 | c.117C>G p.V39= | Silent (SNP) | VAF 12/54 reads (22%) | called by muse, varscan2
- GTF2IRD2 | c.1995G>A p.L665= | Silent (SNP) | VAF 18/185 reads (10%) | catalogued as COSV63101037; called by muse, mutect2, varscan2
- INPP4A | c.1254C>T p.I418= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV99305612; called by muse, mutect2, varscan2
- LSAMP | c.444C>T p.N148= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs780626885, COSV61282793; called by muse, mutect2, varscan2
- MAGEC1 | c.1398T>G p.T466= | Silent (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- MCTP2 | c.999C>A p.A333= | Silent (SNP) | VAF 16/217 reads (7%) | catalogued as COSV100537804; called by muse, mutect2
- MYH7 | c.375C>G p.V125= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100806800; called by muse, mutect2, varscan2
- OR2S2 | c.633G>A p.P211= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs760796586, COSV59531518; called by muse, mutect2, varscan2
- PCDHA6 | c.1671C>T p.D557= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV65341441; called by muse, mutect2, varscan2
- PCDHB3 | c.2112G>A p.S704= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV50612208, COSV50617233; called by muse, mutect2, varscan2
- PIK3C2G | c.408T>G p.A136= | Silent (SNP) | VAF 4/29 reads (14%) | called by mutect2, varscan2
- PLCL1 | c.2277G>A p.A759= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as rs1253640089, COSV70843301; called by muse, mutect2, varscan2
- RPS6KL1 | c.159G>A p.A53= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs760879613, COSV100665243; called by mutect2, varscan2
- SDHA | c.1935C>T p.I645= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as rs762128553, COSV53768838; ClinVar: likely benign; called by muse, mutect2
- SF3A3 | c.1344T>C p.N448= | Silent (SNP) | VAF 16/200 reads (8%) | catalogued as rs1557749143; called by muse, mutect2
- STRC | c.4455C>G p.L1485= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs764576756, COSV55853982; called by muse, mutect2, varscan2
- TEKT3 | c.1293C>A p.I431= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100107334; called by muse, mutect2, varscan2
- TNFRSF19 | c.843C>T p.N281= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs781345372, COSV99947826; called by muse, mutect2, varscan2
- GCNT2 | c.926-35276C>T | Intron (SNP) | VAF 22/81 reads (27%) | catalogued as rs775325397, COSV53942623; called by muse, mutect2, varscan2
- HOXD4 | chr2:176150360 G>A | 5'Flank (SNP) | VAF 9/79 reads (11%) | catalogued as rs1457349764; called by muse, mutect2, varscan2
- MIR30A | n.59T>C | RNA (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
